Somatic mutation profile of tumor specimen 0DF2AV from CCDI case PBBJUH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.3 years (848 days).
Specimen 0DF2AV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd510796-b5f8-4dd8-91a4-e02b2aaac49a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF2B9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cda66472-1799-4469-8200-b1f3512ee9e3

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, RNA 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGK | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 212/2034 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1466996749, COSV62595929; called by muse, mutect2, varscan2
- CHDH | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 91/630 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs757738588; called by muse, mutect2, varscan2
- OR6A2 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 20/601 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as rs896360835, COSV60265624; called by muse, mutect2
- TLNRD1 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1330211138, COSV99146108; called by muse, mutect2
- ESPN | c.1171A>G p.K391E | Missense Mutation (SNP) | VAF 143/694 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KMT2D | c.15650G>C p.W5217S | Missense Mutation (SNP) | VAF 77/463 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- L3MBTL1 | c.1713C>A p.I571= (on ENST00000418998 / NM_001377303.1; = p.I481= on NM_015478.7) | Splice Region (SNP) | VAF 110/651 reads (17%) | called by muse, mutect2, varscan2
- MAP1B | c.2881C>T p.H961Y | Missense Mutation (SNP) | VAF 93/775 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCKAP1L | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 124/767 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RHBDF1 | c.1213T>C p.F405L | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2
- SGK1 | c.1055A>T p.H352L | Missense Mutation (SNP) | VAF 87/608 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT10 | c.771T>A p.D257E | Missense Mutation (SNP) | VAF 96/913 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TEX13A | c.1217A>C p.Q406P | Missense Mutation (SNP) | VAF 167/414 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- UNC79 | c.5598G>T p.Q1866H (on ENST00000393151 / NM_001346218.2; = p.Q1689H on NM_020818.5) | Missense Mutation (SNP) | VAF 71/365 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ITIH5 | c.1230G>A p.T410= | Silent (SNP) | VAF 34/210 reads (16%) | catalogued as rs746173381, COSV53669106; called by muse, mutect2, varscan2
- KLB | c.1623G>A p.S541= | Silent (SNP) | VAF 44/907 reads (5%) | catalogued as rs1261938126; called by muse, mutect2
- PPFIA4 | c.3486G>A p.P1162= (on ENST00000447715; = p.P1163= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 149/608 reads (25%) | catalogued as COSV55313830; called by muse, mutect2, varscan2
- TUSC1 | c.84G>A p.G28= | Silent (SNP) | VAF 58/241 reads (24%) | called by muse, mutect2, varscan2
- ATAD5 | c.3607+43dup | Intron (INS) | VAF 57/330 reads (17%) | catalogued as rs1243990064; called by mutect2, varscan2
- ZNF286B | n.1171C>A | RNA (SNP) | VAF 208/858 reads (24%) | called by muse, mutect2, varscan2
